Somatic mutation profile of tumor specimen TCGA-44-7670-01A (aliquot TCGA-44-7670-01A-11D-2063-08) from TCGA case TCGA-44-7670, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.6 years (17,392 days).
Specimen TCGA-44-7670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 418928d4-30ef-4e1c-ab3c-957ef4948ff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7670-10A (Blood Derived Normal), aliquot TCGA-44-7670-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02c37aa1-ff1e-4548-ace1-0953351e6d01

The open-access MAF lists 1,178 somatic variants for this specimen: 912 protein-altering or splice-affecting, 238 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 763, Silent 238, Nonsense Mutation 77, Frame Shift Del 28, Splice Site 22, RNA 15, Frame Shift Ins 10, Splice Region 8, Intron 6, 3'UTR 3, 3'Flank 2, In Frame Del 2.

Variants (750 of 1,178; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2391G>A p.W797* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs137852565, CM900027, COSV65954641; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as rs128626239, CM940340, COSV55870587; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT tolerated, low confidence (1); PolyPhen benign (0.134); catalogued as COSV51105249; called by muse, mutect2, varscan2
- SMARCA2 | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs886041299, COSV61807238; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3604G>T p.G1202C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875239, CM122548, COSV61807248, COSV61811057; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57923936; called by muse, mutect2, varscan2
- ABCA10 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV52222018; called by muse, mutect2, varscan2
- ABCA12 | c.1967C>A p.P656Q (on ENST00000272895 / NM_173076.3; = p.P338Q on NM_015657.3) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV55958952; called by muse, mutect2, varscan2
- ABCB1 | c.2920G>T p.V974F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55950668; called by muse, mutect2, varscan2
- ABCB11 | c.3842A>G p.Q1281R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV55590308; called by muse, mutect2, varscan2
- ABCC6 | c.996C>T p.L332= | Splice Region (SNP) | VAF 11/38 reads (29%) | catalogued as COSV52743756; called by muse, mutect2, varscan2
- ABCG4 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1195565008, COSV56643275, COSV56643566; called by muse, mutect2, varscan2
- AC024598.1 | c.1301T>A p.L434* | Nonsense Mutation (SNP) | VAF 66/219 reads (30%) | catalogued as COSV60824048; called by muse, mutect2, varscan2
- ACBD4 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV58851871; called by muse, mutect2, varscan2
- ACO1 | c.988T>A p.L330I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs149639885; called by mutect2, varscan2
- ACOT11 | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV59346330, COSV59348324; called by muse, mutect2, varscan2
- ACSM5 | c.847T>A p.F283I | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV59371311; called by muse, mutect2, varscan2
- ACTG2 | c.939G>T p.R313S | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV61828308; called by muse, mutect2, varscan2
- ACVRL1 | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023319, CM050995, COSV66360180; called by muse, mutect2, varscan2
- ADAM23 | c.1875C>A p.F625L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV52215192; called by muse, mutect2, varscan2
- ADAMTS12 | c.3410C>A p.T1137N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV61262748; called by muse, mutect2, varscan2
- ADAMTS13 | c.4080C>T p.I1360= | Splice Region (SNP) | VAF 15/25 reads (60%) | catalogued as COSV52469876; called by muse, mutect2, varscan2
- ADAMTS14 | c.2552G>A p.W851* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100941962, COSV64601972; called by muse, mutect2, varscan2
- ADAMTS20 | c.4543C>G p.Q1515E | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101238988, COSV67131277; called by muse, mutect2, varscan2
- ADAMTS20 | c.79C>G p.H27D | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV67131286; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1984G>T p.G662* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV54447420; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2158G>T p.G720* | Nonsense Mutation (SNP) | VAF 46/80 reads (58%) | catalogued as COSV54447444; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3898C>A p.H1300N | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54439786, COSV54447471; called by muse, mutect2, varscan2
- ADGRA2 | c.2873C>A p.P958H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); catalogued as COSV55103466; called by muse, mutect2
- ADGRB3 | c.3851G>T p.C1284F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53244188; called by muse, varscan2
- ADGRF4 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV51952300; called by muse, mutect2, varscan2
- ADRA1A | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV52360886, COSV52363717; called by muse, mutect2, varscan2
- AGAP4 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1280629766; called by muse, mutect2
- AGMO | c.481A>T p.R161* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV61112298; called by muse, mutect2, varscan2
- AGO4 | c.1425G>T p.M475I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV64617121; called by muse, mutect2, varscan2
- AHCTF1 | c.6340G>A p.E2114K (on ENST00000366508; = p.E2088K on NM_015446.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV58249768; called by muse, mutect2, varscan2
- ALDH3A2 | c.1307A>T p.N436I | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51566675; called by muse, mutect2, varscan2
- ALKBH5 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV67686976; called by muse, mutect2, varscan2
- AMER1 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV57660643; called by muse, mutect2, varscan2
- ANK3 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV55057389; called by muse, mutect2, varscan2
- ANKS6 | c.1741G>T p.G581W | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs750034139, COSV62049312, COSV62050225; called by muse, mutect2, varscan2
- AP5S1 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs149938656; called by muse, mutect2, varscan2
- APLP2 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 74/243 reads (30%) | catalogued as COSV53840148; called by muse, mutect2, varscan2
- APOB | c.10343C>A p.T3448N | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV51934923; called by muse, mutect2, varscan2
- APOB | c.10165A>G p.R3389G | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV51934934; called by muse, mutect2, varscan2
- APOBEC3G | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV68470280; called by muse, mutect2, varscan2
- ARHGAP1 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); catalogued as COSV56319340; called by muse, mutect2, varscan2
- ARHGAP30 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs763155341, COSV63516460; called by muse, mutect2, varscan2
- ARHGAP6 | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57295742; called by muse, mutect2, varscan2
- ARID1A | c.2101G>T p.G701C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61377430; called by muse, mutect2, varscan2
- ARMH3 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV64234823; called by muse, mutect2, varscan2
- ASMT | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67109845; called by muse, mutect2, varscan2
- ASTN2 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.935); catalogued as COSV57776428; called by muse, mutect2, varscan2
- ASXL3 | c.1872C>A p.S624R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs778966078, COSV52465685; called by muse, mutect2, varscan2
- ASXL3 | c.6745T>C p.*2249Qext*17 | Nonstop Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as COSV52465699; called by muse, mutect2, varscan2
- ATE1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV56436308; called by muse, mutect2, varscan2
- ATP10D | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV56706466, COSV56707301; called by muse, mutect2, varscan2
- ATP1A1 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV55191183; called by muse, mutect2, varscan2
- ATP5MF | c.31+1G>T p.X11_splice | Splice Site (SNP) | VAF 27/44 reads (61%) | catalogued as COSV99461735; called by muse, mutect2, varscan2
- ATP8B3 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59542658; called by muse, mutect2, varscan2
- ATPSCKMT | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV54726788; called by muse, mutect2, varscan2
- ATRX | c.2030C>A p.S677* | Nonsense Mutation (SNP) | VAF 51/184 reads (28%) | catalogued as COSV100969776, COSV64876383; called by muse, mutect2, varscan2
- BBS2 | c.940+1G>T p.X314_splice | Splice Site (SNP) | VAF 36/127 reads (28%) | catalogued as COSV55326403; called by muse, mutect2, varscan2
- BCAP31 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV61451650; called by muse, mutect2, varscan2
- BCL2 | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61379679; called by muse, mutect2, varscan2
- BEND2 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV66215791, COSV66216816; called by muse, mutect2, varscan2
- BNIP5 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV71325529; called by muse, mutect2, varscan2
- BPIFC | c.486C>A p.Y162* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV55912438; called by muse, mutect2, varscan2
- BRCA2 | c.7822C>T p.P2608S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66453555; called by muse, mutect2, varscan2
- BTNL2 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.499); catalogued as COSV66630714; called by muse, mutect2, varscan2
- BTRC | c.164C>A p.S55* (on ENST00000370187 / NM_033637.4; = p.S19* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV64561279; called by muse, mutect2, varscan2
- BUB1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as rs754507524, COSV57063542; called by muse, mutect2, varscan2
- C11orf54 | c.714G>T p.L238F (on ENST00000331239; = p.L188F on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100487026, COSV58680425; called by muse, mutect2, varscan2
- C18orf25 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV56366311; called by muse, mutect2, varscan2
- C1orf112 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs756662466, COSV53678539; called by muse, mutect2, varscan2
- C1orf54 | c.290C>G p.T97R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV64859583; called by muse, mutect2, varscan2
- C2orf80 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58016713; called by muse, mutect2, varscan2
- C8B | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64777581, COSV64778386; called by muse, mutect2, varscan2
- CACNA1D | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV55446739; called by muse, mutect2, varscan2
- CACNA1I | c.2482T>C p.Y828H | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60807981; called by muse, mutect2, varscan2
- CACNB2 | c.1234G>A p.G412R (on ENST00000324631 / NM_201596.3; = p.G357R on NM_000724.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56623364; called by muse, mutect2, varscan2
- CAMK2D | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56430270; called by muse, mutect2, varscan2
- CAND1 | c.1213A>T p.T405S | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV73338586; called by muse, mutect2, varscan2
- CAPN6 | c.774T>A p.D258E | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as COSV60694940; called by muse, mutect2, varscan2
- CAPRIN1 | c.1707G>T p.V569= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as COSV58219759; called by muse, mutect2, varscan2
- CARMIL1 | c.2845G>T p.V949L | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs750731342, COSV61517391; called by muse, mutect2, varscan2
- CAVIN4 | c.670A>G p.R224G | Missense Mutation (SNP) | VAF 69/98 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56867174; called by muse, mutect2, varscan2
- CC2D2A | c.3820C>T p.Q1274* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV67502949, COSV67503599; called by muse, mutect2
- CCDC120 | c.737G>T p.W246L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.121); catalogued as COSV64515160; called by muse, mutect2, varscan2
- CCDC40 | c.1759A>G p.R587G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as rs1265686018, COSV66474674; called by muse, mutect2, varscan2
- CCDC73 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs959113377, COSV58798381; called by muse, mutect2, varscan2
- CCDC87 | c.1780G>T p.V594L | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59579065; called by muse, mutect2, varscan2
- CCNB3 | c.787A>T p.M263L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV52073436; called by muse, mutect2
- CCNB3 | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as COSV52073446; called by muse, mutect2
- CCNF | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV53539930; called by muse, mutect2, varscan2
- CCT2 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV54740150; called by muse, mutect2, varscan2
- CD163 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV63132174; called by muse, mutect2, varscan2
- CD200R1 | c.496G>T p.V166L (on ENST00000471858 / NM_170780.3; = p.V189L on NM_138806.4) | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV55600582; called by muse, mutect2, varscan2
- CD244 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59238006; called by muse, mutect2, varscan2
- CD86 | c.112C>A p.L38M (on ENST00000330540 / NM_175862.5; = p.L32M on NM_006889.4) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52606799; called by muse, mutect2, varscan2
- CDC14B | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV55788021; called by muse, mutect2, varscan2
- CDC34 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53116744; called by muse, mutect2, varscan2
- CDC42BPA | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV62010678; called by muse, mutect2, varscan2
- CDH10 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV52580492; called by muse, mutect2, varscan2
- CDH4 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV64654141, COSV64673136; called by muse, mutect2, varscan2
- CDH8 | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54866487; called by muse, mutect2, varscan2
- CDHR2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV56138581; called by muse, mutect2, varscan2
- CDK14 | c.508del p.E170Kfs*16 (on ENST00000380050 / NM_001287135.2; = p.E152Kfs*16 on NM_012395.3) | Frame Shift Del (DEL) | VAF 114/204 reads (56%) | catalogued as COSV99723863, COSV99726963; called by mutect2, pindel, varscan2
- CDKL5 | c.2671C>A p.Q891K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV66111263, COSV66111271; called by muse, mutect2, varscan2
- CELF3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1413587062, COSV51883374; called by muse, mutect2, varscan2
- CELSR3 | c.2625C>A p.S875R | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50858554; called by muse, mutect2, varscan2
- CENPF | c.9142-1G>T p.X3048_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV65274889; called by muse, mutect2, varscan2
- CENPK | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54468191; called by muse, mutect2, varscan2
- CERKL | c.1547C>A p.A516D (on ENST00000339098 / NM_001030311.2; = p.A490D on NM_201548.5) | Missense Mutation (SNP) | VAF 131/205 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.372); catalogued as COSV59207364; called by muse, mutect2, varscan2
- CERS5 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV58189125, COSV58189786; called by muse, mutect2, varscan2
- CES5A | c.1132C>G p.P378A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51866252; called by muse, mutect2, varscan2
- CES5A | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99307551; called by muse, mutect2, varscan2
- CFAP45 | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV63649013; called by muse, mutect2, varscan2
- CFAP74 | c.4737G>T p.Q1579H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV60587018; called by muse, mutect2, varscan2
- CHD1 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV52340118; called by muse, mutect2, varscan2
- CHI3L1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs138989209; called by muse, mutect2, varscan2
- CHM | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV63301872; called by muse, mutect2, varscan2
- CHRM2 | c.955A>G p.N319D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.348); catalogued as COSV57771999; called by muse, mutect2, varscan2
- CHST6 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60000100; called by muse, mutect2, varscan2
- CLEC14A | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV60562517; called by muse, mutect2, varscan2
- CLEC18B | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60577490; called by muse, mutect2, varscan2
- CNDP2 | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60839885; called by muse, mutect2, varscan2
- CNKSR2 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV54255979; called by muse, mutect2, varscan2
- CNTN3 | c.2704+1G>C p.X902_splice | Splice Site (SNP) | VAF 68/120 reads (57%) | catalogued as rs763671270, COSV55170985, COSV99725644, COSV99726218; called by muse, mutect2, varscan2
- CNTNAP5 | c.1583T>A p.V528D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70485480; called by muse, mutect2, varscan2
- COL12A1 | c.8088G>T p.R2696S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.155); catalogued as COSV100486127, COSV59395809; called by muse, mutect2, varscan2
- COL16A1 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54705546; called by muse, mutect2, varscan2
- COL19A1 | c.2374G>T p.G792C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59572641; called by muse, mutect2, varscan2
- COL20A1 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV58917049; called by muse, mutect2, varscan2
- COL20A1 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as COSV58917066; called by muse, mutect2, varscan2
- COL20A1 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58917090; called by muse, varscan2
- COL22A1 | c.1675C>A p.P559T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.874); catalogued as COSV57336280; called by muse, mutect2, varscan2
- COL24A1 | c.3671A>T p.E1224V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV100993342; called by muse, mutect2, varscan2
- COL2A1 | c.1939G>C p.A647P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.093); catalogued as COSV61530429; called by muse, mutect2, varscan2
- COL3A1 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.283); catalogued as COSV58586894, COSV58587645; called by muse, mutect2, varscan2
- COL4A5 | c.628G>T p.G210* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV60361349; called by muse, mutect2, varscan2
- COL5A1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368168386, COSV65668842; called by muse, mutect2, varscan2
- COL5A2 | c.4156C>A p.Q1386K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66409672, COSV66416123; called by muse, mutect2, varscan2
- COL6A2 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs766193071, COSV56004710; called by muse, mutect2, varscan2
- COL8A2 | c.2057A>G p.Y686C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57441717; called by muse, mutect2, varscan2
- COLGALT1 | c.1201C>G p.H401D | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.698); catalogued as COSV53108886; called by muse, mutect2, varscan2
- COQ10B | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55836318; called by muse, mutect2
- CPS1 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1341329556, COSV51809743; called by muse, mutect2, varscan2
- CRACD | c.2273C>G p.A758G | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51720773; called by muse, mutect2, varscan2
- CREBBP | c.7201G>T p.G2401W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV52123462; called by muse, mutect2, varscan2
- CRISP2 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV59254638, COSV59255869; called by muse, mutect2, varscan2
- CRISP2 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1339632528, COSV100189174, COSV59254645; called by muse, mutect2, varscan2
- CSGALNACT2 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV65675578; called by muse, mutect2, varscan2
- CSMD2 | c.4307C>A p.P1436H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53908229; called by muse, mutect2, varscan2
- CSMD2 | c.1070C>A p.S357* | Nonsense Mutation (SNP) | VAF 53/184 reads (29%) | catalogued as COSV53876686, COSV53911244; called by muse, mutect2, varscan2
- CSMD3 | c.5353G>T p.G1785* (on ENST00000297405 / NM_001363185.1; = p.G1681* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV52266923, COSV52351481; called by muse, mutect2, varscan2
- CSMD3 | c.2187G>A p.M729I (on ENST00000297405 / NM_001363185.1; = p.M625I on NM_052900.3) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV52157784, COSV99847709; called by muse, mutect2, varscan2
- CSPP1 | c.2013G>T p.M671I (on ENST00000676605; = p.M630I on NM_024790.6) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51584304; called by mutect2, varscan2
- CST2 | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs200469888, COSV59030937, COSV59032025; called by muse, mutect2, varscan2
- CTAGE1 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV66943410; called by muse, mutect2, varscan2
- CTCFL | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 225/500 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV54773901; called by muse, mutect2, varscan2
- CTNNA2 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV63557736, COSV63565933; called by muse, mutect2
- CTNNA2 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV63565941; called by muse, mutect2, varscan2
- CTNNA2 | c.2121C>A p.S707R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs780278071, COSV100562322, COSV58151912; called by muse, mutect2, varscan2
- CTSG | c.761C>G p.P254R | Missense Mutation (SNP) | VAF 145/284 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV53534982, COSV99361529; called by muse, mutect2, varscan2
- CTSG | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs745616582, COSV99361534; called by muse, mutect2, varscan2
- CYP2B6 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57843664; called by muse, mutect2, varscan2
- DCAF12L1 | c.127A>T p.R43W | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV64421771; called by muse, mutect2, varscan2
- DCAF8L1 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs762582589, COSV71595274; called by muse, mutect2, varscan2
- DCC | c.3262G>T p.G1088C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71431792; called by muse, mutect2, varscan2
- DCDC1 | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60842193, COSV60847842; called by muse, mutect2, varscan2
- DCHS1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.902); catalogued as COSV55035404; called by muse, mutect2, varscan2
- DCUN1D1 | c.701-1G>T p.X234_splice | Splice Site (SNP) | VAF 49/77 reads (64%) | catalogued as COSV99489898; called by muse, mutect2, varscan2
- DDN | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.693); catalogued as COSV70404591, COSV70405164; called by muse, varscan2
- DDRGK1 | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1454160103, COSV63226797; called by muse, mutect2, varscan2
- DDX28 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100193005; called by muse, mutect2, varscan2
- DDX28 | c.1312G>T p.G438* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100193007; called by muse, mutect2, varscan2
- DEFB126 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66694816; called by muse, mutect2, varscan2
- DEK | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV55237572; called by muse, mutect2
- DENND5A | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.241); catalogued as rs1488939951, COSV60233523; called by muse, mutect2, varscan2
- DGCR8 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV61225932, COSV61226632; called by muse, mutect2
- DHX16 | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV64580549; called by muse, mutect2, varscan2
- DHX37 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV100413038; called by muse, mutect2, varscan2
- DIAPH2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV61269526; called by muse, mutect2, varscan2
- DISP1 | c.3568G>C p.E1190Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52658701; called by muse, mutect2, varscan2
- DLC1 | c.2981G>T p.R994M (on ENST00000276297 / NM_001348081.2; = p.R557M on NM_006094.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52303415; called by muse, mutect2, varscan2
- DMD | c.9239C>A p.T3080K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58910089; called by muse, mutect2, varscan2
- DMD | c.5330C>T p.S1777F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV63754371; called by muse, mutect2, varscan2
- DMD | c.1482G>C p.K494N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55867424, COSV55870562; called by muse, mutect2, varscan2
- DNAAF1 | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57577221; called by muse, mutect2, varscan2
- DNAH1 | c.10179G>T p.Q3393H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as rs761169388, COSV70228936; called by muse, mutect2, varscan2
- DNAH10 | c.10209G>T p.M3403I (on ENST00000409039; = p.M3342I on NM_207437.3) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV68993603; called by muse, mutect2, varscan2
- DNAH3 | c.5747C>G p.S1916* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV54520966; called by muse, mutect2, varscan2
- DNAH3 | c.2868C>A p.H956Q | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54520987, COSV99769623; called by muse, mutect2, varscan2
- DNAH9 | c.676T>A p.Y226N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV52348983; called by muse, mutect2, varscan2
- DNER | c.1890C>A p.S630R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV59166060; called by muse, mutect2, varscan2
- DOCK5 | c.3337A>T p.T1113S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV52401450; called by muse, mutect2, varscan2
- DOCK6 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV53914690; called by muse, mutect2, varscan2
- DOCK8 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV66619993; called by muse, mutect2, varscan2
- DRC7 | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61054591; called by muse, mutect2, varscan2
- DRD5 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV58577931; called by muse, varscan2
- DRD5 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV58577941; called by muse, varscan2
- DRD5 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58577949; called by muse, mutect2, varscan2
- DSC2 | c.716A>T p.N239I | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51864530; called by muse, mutect2, varscan2
- DSCAM | c.4217G>T p.G1406V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101260201; called by muse, mutect2, varscan2
- DSCAM | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV68026464; called by muse, mutect2, varscan2
- DSG4 | c.2296C>A p.L766M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV57391557; called by muse, mutect2, varscan2
- DST | c.16445G>T p.W5482L (on ENST00000361203 / NM_001374722.1; = p.W3070L on NM_015548.5) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55013786; called by muse, mutect2
- DST | c.16443A>T p.R5481S (on ENST00000361203 / NM_001374722.1; = p.R3069S on NM_015548.5) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55013811; called by muse, mutect2
- DST | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56815955; called by muse, mutect2, varscan2
- DTNA | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52002626; called by muse, mutect2, varscan2
- DUSP5 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs1452914380, COSV63645860; called by muse, mutect2, varscan2
- DYDC2 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV55472199; called by muse, mutect2, varscan2
- DYNC2H1 | c.10522G>T p.D3508Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62093912; called by muse, mutect2, varscan2
- DZIP3 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 85/152 reads (56%) | catalogued as COSV64312060; called by muse, mutect2, varscan2
- E2F7 | c.2070G>T p.K690N | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59739760; called by muse, mutect2, varscan2
- E2F7 | c.160T>G p.L54V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as COSV59739782; called by muse, mutect2, varscan2
- ECEL1 | c.1152G>T p.Q384H | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV58812219; called by muse, mutect2, varscan2
- EDEM2 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65712961; called by muse, mutect2, varscan2
- EEF2K | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53781706; called by muse, mutect2, varscan2
- EFTUD2 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs747182001, COSV68183039; called by muse, mutect2, varscan2
- EHHADH | c.1822C>G p.H608D | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV51630080; called by muse, mutect2
- EHHADH | c.1670G>T p.R557M | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51630091; called by muse, mutect2, varscan2
- ELAVL4 | c.1134C>A p.H378Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV63915783; called by muse, mutect2, varscan2
- ELF1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV53498893; called by muse, mutect2, varscan2
- EMID1 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61829401; called by muse, mutect2, varscan2
- ENTHD1 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57320148; called by muse, mutect2, varscan2
- ENY2 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV60565601; called by muse, mutect2, varscan2
- ERBB4 | c.2597G>A p.R866K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); catalogued as COSV61486132; called by muse, mutect2, varscan2
- ERBB4 | c.884-2A>T p.X295_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as rs1475499434, COSV99623904; called by mutect2, varscan2
- ERC2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV55621152; called by muse, mutect2, varscan2
- ERCC2 | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 98/162 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67263346; called by muse, mutect2, varscan2
- ESYT1 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV57272914; called by muse, mutect2, varscan2
- EXOSC7 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV55556520; called by muse, varscan2
- EXOSC7 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55556527, COSV55557394; called by muse, varscan2
- EYA2 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs267605970, COSV57942936; called by muse, mutect2, varscan2
- EYS | c.1459G>T p.G487* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV60985217; called by muse, mutect2
- F2 | c.1312A>T p.I438F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV61315769; called by muse, mutect2, varscan2
- F5 | c.5986G>T p.A1996S | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.468); catalogued as COSV63123774; called by muse, mutect2, varscan2
- F5 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63123781; called by muse, mutect2, varscan2
- F8 | c.4271C>A p.T1424N | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV64273329; called by muse, mutect2, varscan2
- F9 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD930979, CM045149, CM940738, COSV54380220; called by muse, mutect2, varscan2
- FAM135B | c.2760C>A p.N920K | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV52723978, COSV99427814; called by muse, mutect2, varscan2
- FAM217B | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV62564312; called by muse, mutect2, varscan2
- FAM3D | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62558241; called by muse, mutect2, varscan2
- FAM47B | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.242); catalogued as COSV61453858; called by muse, mutect2, varscan2
- FAM47C | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV63726462; called by muse, mutect2, varscan2
- FAM71D | c.97T>G p.L33V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61295421; called by muse, mutect2, varscan2
- FANCF | c.1056A>T p.L352F | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV59416248; called by muse, mutect2, varscan2
- FANK1 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64158283; called by muse, mutect2, varscan2
- FAP | c.1862G>T p.W621L | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51861665; called by muse, mutect2, varscan2
- FAR1 | c.925A>T p.S309C | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV61384808; called by muse, mutect2, varscan2
- FAT1 | c.2392G>T p.G798W | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71673820; called by muse, mutect2, varscan2
- FBL | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55682575; called by muse, mutect2, varscan2
- FBXL4 | c.1380T>G p.S460R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57745694, COSV57746940; called by muse, mutect2, varscan2
- FCGR2B | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV52681477; called by muse, mutect2, varscan2
- FCRL6 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as COSV58941115; called by muse, mutect2, varscan2
- FERMT1 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54093052; called by muse, mutect2, varscan2
- FHL1 | c.112A>T p.N38Y | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61780936; called by muse, mutect2, varscan2
- FIGLA | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 105/490 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV60089093; called by muse, mutect2, varscan2
- FLG | c.6562A>T p.S2188C | Missense Mutation (SNP) | VAF 69/554 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV64236556, COSV64241700, COSV64244453; called by muse, mutect2, varscan2
- FLG | c.117G>C p.K39N | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.586); catalogued as COSV64241707, COSV64244634, COSV64245696; called by muse, mutect2, varscan2
- FMN2 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV60429933; called by muse, mutect2, varscan2
- FNTA | c.995A>T p.D332V | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV56490015; called by muse, mutect2, varscan2
- FREM1 | c.6453T>A p.C2151* | Nonsense Mutation (SNP) | VAF 30/40 reads (75%) | catalogued as COSV66523301; called by muse, mutect2, varscan2
- FREM1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101085234, COSV66523424; called by muse, mutect2, varscan2
- FRMPD3 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.979); catalogued as COSV52194838, COSV99346340; called by muse, mutect2, varscan2
- FRRS1 | c.1248G>T p.M416I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV54922019; called by muse, mutect2, varscan2
- FYB2 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs755188774, COSV58583616, COSV58585007; called by muse, mutect2, varscan2
- FZD10 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 43/99 reads (43%) | catalogued as COSV57473557, COSV57474425, COSV99969343; called by muse, mutect2, varscan2
- GABRG2 | c.1393C>T p.R465* (on ENST00000361925 / NM_001375343.1; = p.R425* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/80 reads (60%) | catalogued as rs1554101224, COSV62723646; called by muse, varscan2
- GABRG2 | c.1394G>C p.R465P (on ENST00000361925 / NM_001375343.1; = p.R425P on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100729700, COSV62715569; called by muse, varscan2
- GABRG2 | c.1480T>G p.C494G (on ENST00000361925 / NM_001375343.1; = p.C454G on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.991); catalogued as COSV62717940; called by muse, varscan2
- GABRQ | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV64781949; called by muse, mutect2, varscan2
- GABRR2 | c.839G>T p.W280L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246968103, COSV68764876; called by muse, varscan2
- GALNT13 | c.919A>T p.T307S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67220674; called by muse, mutect2, varscan2
- GALNT8 | c.1593+1G>C p.X531_splice | Splice Site (SNP) | VAF 11/64 reads (17%) | catalogued as COSV52897301; called by muse, mutect2, varscan2
- GBP6 | c.66G>T p.L22F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.098); catalogued as rs758780589, COSV65011457; called by muse, mutect2, varscan2
- GCNA | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV65466711; called by muse, varscan2
- GDI1 | c.1272G>T p.M424I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50131144; called by muse, mutect2, varscan2
- GFRAL | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV61230878; called by muse, mutect2, varscan2
- GLMN | c.1295T>A p.L432* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV64860390; called by muse, mutect2, varscan2
- GLP1R | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV64714277, COSV64714930; called by muse, mutect2, varscan2
- GLUD2 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV60151923; called by muse, mutect2, varscan2
- GLUD2 | c.1553C>A p.A518D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV60151929; called by muse, mutect2, varscan2
- GNAS | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV58334881; called by muse, mutect2, varscan2
- GNB3 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.486); catalogued as COSV51833039; called by mutect2, varscan2
- GOLGA3 | c.2005G>T p.D669Y | Missense Mutation (SNP) | VAF 152/477 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52631022; called by muse, mutect2, varscan2
- GP1BA | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs1164809422, COSV56699441; called by muse, mutect2, varscan2
- GPATCH3 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV64652065; called by muse, mutect2, varscan2
- GPC4 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.428); catalogued as COSV100895481; called by muse, mutect2, varscan2
- GPR101 | c.1362T>A p.Y454* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV53238846; called by muse, mutect2, varscan2
- GPR137B | c.403T>A p.Y135N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63990928; called by muse, mutect2, varscan2
- GPR143 | c.986G>T p.W329L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs1465488835, COSV101102238; called by muse, mutect2, varscan2
- GPRIN3 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV60884862; called by muse, mutect2, varscan2
- GRAMD1C | c.354G>T p.W118C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63982711; called by muse, mutect2, varscan2
- GRIA3 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52059190; called by muse, mutect2, varscan2
- GRIA3 | c.2662G>T p.G888* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV52047746, COSV52077566; called by muse, mutect2, varscan2
- GRIK1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58717884; called by muse, mutect2, varscan2
- GRIK5 | c.2095A>C p.S699R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782270982, COSV53478505; called by muse, mutect2, varscan2
- GRM1 | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51144364; called by muse, mutect2, varscan2
- GRM3 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64471509, COSV64472119; called by muse, mutect2, varscan2
- GRSF1 | c.685A>T p.N229Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV54655296; called by muse, mutect2
- H2BW1 | c.131C>G p.T44S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV54220267; called by muse, mutect2, varscan2
- H3C4 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.217); catalogued as COSV61911918; called by muse, mutect2, varscan2
- HACL1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58254526; called by muse, mutect2, varscan2
- HARBI1 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV56319329; called by muse, mutect2, varscan2
- HCCS | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV58239101; called by muse, mutect2, varscan2
- HCN1 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs141383188; called by muse, varscan2
- HCN1 | c.2039C>G p.S680C | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57509945; called by muse, varscan2
- HCN1 | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57509953; called by muse, mutect2, varscan2
- HEATR5B | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51852538; called by muse, mutect2, varscan2
- HECTD1 | c.3697G>C p.G1233R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237388; called by muse, mutect2, varscan2
- HECTD4 | c.2599A>C p.K867Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.35); catalogued as COSV61179301; called by muse, mutect2, varscan2
- HIPK3 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV100305795; called by muse, mutect2, varscan2
- HLA-DQB1 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV66571086; called by muse, mutect2, varscan2
- HMBOX1 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55068097; called by muse, mutect2, varscan2
- HMCN1 | c.1926G>C p.K642N | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as COSV54892250, COSV54899643; called by muse, mutect2, varscan2
- HMGCLL1 | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs757570289, COSV51444626; called by muse, mutect2, varscan2
- HMX3 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV63501686; called by muse, mutect2, varscan2
- HNRNPUL1 | c.333C>A p.Y111* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV54562229; called by muse, mutect2, varscan2
- HOXA13 | c.922+1G>T p.X308_splice | Splice Site (SNP) | VAF 21/32 reads (66%) | catalogued as COSV99763607; called by muse, mutect2, varscan2
- HOXB5 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.626); catalogued as COSV53313047; called by muse, mutect2, varscan2
- HRG | c.893C>A p.P298Q | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV51645550, COSV51647179; called by muse, mutect2, varscan2
- HTATSF1 | c.1196C>G p.A399G | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54478841; called by muse, mutect2, varscan2
- HYDIN | c.13165C>G p.Q4389E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV66638960; called by muse, mutect2, varscan2
- IFIT1B | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198000661, COSV65663403; called by muse, mutect2, varscan2
- IFNLR1 | c.1065G>C p.Q355H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV59526402; called by muse, mutect2, varscan2
- IFT140 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV68488496, COSV68504043; called by muse, mutect2, varscan2
- IGF2R | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63629030; called by muse, mutect2, varscan2
- IGHV7-81 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs757421213; called by muse, mutect2, varscan2
- IGSF1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV63837408; called by muse, mutect2, varscan2
- IL16 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV57263486; called by muse, mutect2, varscan2
- IL17A | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 121/139 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV60684405; called by muse, mutect2, varscan2
- IL18RAP | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51825915; called by muse, mutect2, varscan2
- IL2RG | c.1043C>A p.A348D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.051); catalogued as COSV52148343; called by muse, mutect2, varscan2
- IL9 | c.8T>A p.L3Q | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV50853405; called by muse, mutect2, varscan2
- INTS4 | c.472-1G>T p.X158_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as rs1565274789, COSV101417194; called by mutect2, varscan2
- IPO7 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV65685048; called by muse, mutect2, varscan2
- IRS1 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59336333; called by muse, mutect2, varscan2
- ITGA10 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553749370, COSV65197338; called by muse, mutect2, varscan2
- ITGA10 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV65197333; called by muse, mutect2, varscan2
- ITGA7 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57695149; called by muse, varscan2
- ITGAX | c.1660T>A p.Y554N | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51645571; called by muse, mutect2, varscan2
- ITPRIP | c.1173C>A p.F391L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.113); catalogued as COSV53391487, COSV53392273; called by muse, mutect2, varscan2
- JCAD | c.3920G>T p.S1307I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64759573; called by muse, mutect2, varscan2
- JMJD1C | c.4075G>T p.V1359L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV59514744; called by muse, mutect2, varscan2
- KANK4 | c.2306C>A p.T769K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100443366, COSV58092833; called by muse, mutect2, varscan2
- KARS1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV56692113; called by muse, varscan2
- KATNIP | c.1919G>T p.S640I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV55180289; called by muse, mutect2, varscan2
- KCNB2 | c.1608T>A p.S536R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV73050151; called by muse, mutect2, varscan2
- KCNB2 | c.2024C>A p.T675N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.239); catalogued as COSV73049461, COSV73050152; called by muse, mutect2, varscan2
- KCNC2 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54368827; called by muse, mutect2, varscan2
- KCNH3 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV57790752; called by muse, mutect2
- KCNK9 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV57277697, COSV57281483; called by muse, mutect2, varscan2
- KCNV2 | c.592T>A p.C198S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779474861, CM074302, COSV66056138; called by muse, mutect2
- KCTD7 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV51876757; called by muse, mutect2, varscan2
- KDM4A | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64959544; called by muse, mutect2, varscan2
- KHNYN | c.626G>C p.W209S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV52160439; called by muse, mutect2, varscan2
- KIAA1755 | c.3488C>A p.P1163H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.43); catalogued as COSV54076402; called by muse, mutect2, varscan2
- KIF2B | c.2011A>T p.K671* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV52130370; called by muse, mutect2, varscan2
- KIF4B | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV70528455, COSV70529222; called by muse, mutect2, varscan2
- KIF5A | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV99672986; called by muse, mutect2, varscan2
- KLC2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as rs1056037882, COSV57582586; called by muse, mutect2, varscan2
- KLF5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614378, COSV66615313; called by muse, mutect2, varscan2
- KLHL1 | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64765921; called by muse, mutect2, varscan2
- KMT2C | c.7663G>C p.G2555R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51438189; called by muse, mutect2, varscan2
- KMT2E | c.4842C>A p.N1614K | Missense Mutation (SNP) | VAF 67/96 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV57573149, COSV99997183; called by muse, mutect2, varscan2
- KNL1 | c.5454+1G>T p.X1818_splice (on ENST00000346991 / NM_170589.5; = p.X1792_splice on NM_144508.5) | Splice Site (SNP) | VAF 17/34 reads (50%) | catalogued as COSV61154674; called by muse, mutect2, varscan2
- KNTC1 | c.4780C>T p.H1594Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61079555; called by muse, mutect2, varscan2
- KPRP | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV100908775, COSV64221622; called by muse, mutect2, varscan2
- KRT27 | c.516C>A p.D172E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56971735; called by muse, mutect2, varscan2
- KRT6B | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99360745; called by mutect2, varscan2
- KRT72 | c.879C>G p.D293E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV53374267; called by muse, mutect2, varscan2
- KRT79 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57940000, COSV57941402; called by muse, mutect2, varscan2
- KRTAP21-2 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100441147, COSV61684150; called by muse, mutect2, varscan2
- KRTAP9-2 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs923987440, COSV66646659; called by muse, mutect2, varscan2
- KSR1 | c.595G>T p.D199Y (on ENST00000644974 / NM_001367810.1; = p.D62Y on NM_014238.2) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52032534; called by muse, mutect2, varscan2
- KYNU | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51578738; called by muse, mutect2, varscan2
- L1CAM | c.2414G>T p.G805V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100649455, COSV62828037; called by muse, mutect2, varscan2
- L1CAM | c.2023A>G p.T675A | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV62828039; called by muse, mutect2, varscan2
- LAMA1 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.232); catalogued as COSV67536799; called by muse, mutect2
- LAMP2 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV52352997, COSV52353824; called by muse, mutect2, varscan2
- LATS1 | c.1557G>C p.W519C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53590576; called by muse, mutect2, varscan2
- LATS2 | c.2044G>T p.V682L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66875558; called by muse, mutect2, varscan2
- LCT | c.1529G>T p.W510L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51549084; called by muse, mutect2, varscan2
- LCT | c.1528T>A p.W510R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929530; called by muse, mutect2, varscan2
- LDLRAD3 | c.319+1G>T p.X107_splice | Splice Site (SNP) | VAF 34/91 reads (37%) | catalogued as COSV59682419; called by muse, mutect2, varscan2
- LEMD2 | c.1233G>T p.M411I | Missense Mutation (SNP) | VAF 128/335 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53393949; called by muse, varscan2
- LILRA1 | c.1153A>T p.S385C | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52180668; called by muse, mutect2, varscan2
- LONRF3 | c.1509G>T p.L503F (on ENST00000371628 / NM_001031855.3; = p.L462F on NM_024778.5) | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59152130; called by muse, mutect2, varscan2
- LPA | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100307040; called by muse, mutect2, varscan2
- LRP12 | c.1754A>T p.Q585L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV52628727; called by muse, mutect2, varscan2
- LRP2 | c.6642G>T p.K2214N | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55552681; called by muse, mutect2, varscan2
- LRRCC1 | c.2289G>T p.R763S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV64482612; called by muse, mutect2, varscan2
- LRRIQ1 | c.4185G>T p.R1395S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV67830531; called by muse, mutect2, varscan2
- LRRTM3 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63665282, COSV63668633; called by muse, mutect2, varscan2
- LTBP1 | c.3145G>T p.A1049S (on ENST00000404816 / NM_206943.4; = p.A723S on NM_000627.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs200895398, COSV55379111; called by muse, mutect2, varscan2
- LTBP2 | c.1142T>G p.L381R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56207998; called by muse, mutect2, varscan2
- LYG1 | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as COSV57915451; called by muse, mutect2, varscan2
- LYSMD2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99590934; called by muse, mutect2, varscan2
- MAGEB3 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV64397082; called by muse, mutect2, varscan2
- MAGEB4 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV64397085; called by muse, mutect2, varscan2
- MAGEC1 | c.2672T>A p.L891* | Nonsense Mutation (SNP) | VAF 53/196 reads (27%) | catalogued as COSV53572632; called by muse, mutect2, varscan2
- MAGI1 | c.3496A>G p.I1166V (on ENST00000402939 / NM_001033057.2; = p.I1195V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58325978; called by muse, mutect2, varscan2
- MAGI3 | c.4184C>G p.S1395C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as COSV56835078; called by muse, mutect2, varscan2
- MAMLD1 | c.930G>T p.L310F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53374698; called by muse, mutect2, varscan2
- MAMLD1 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV53374729; called by muse, varscan2
- MAP2 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV52290533; called by muse, mutect2, varscan2
- MAP3K15 | c.2736C>G p.N912K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as rs1569202266, COSV58829962; called by muse, mutect2, varscan2
- MAP3K15 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.71); catalogued as rs1316690436, COSV58829985; called by muse, mutect2, varscan2
- MCEE | c.441A>T p.E147D | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54905880; called by muse, mutect2
- MDC1 | c.3581C>G p.S1194C | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV64524559, COSV64525451; called by muse, mutect2, varscan2
- MDGA2 | c.1264C>A p.R422S (on ENST00000399232 / NM_001113498.2; = p.R124S on NM_182830.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV62092387; called by muse, mutect2, varscan2
- MDN1 | c.3881G>C p.W1294S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV101021357; called by muse, mutect2, varscan2
- MED13 | c.2621C>G p.S874C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1282730317, COSV67263470; called by muse, mutect2, varscan2
- MEOX2 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 54/91 reads (59%) | catalogued as rs376342964, COSV56289846; called by muse, mutect2, varscan2
- MFAP3L | c.1120A>T p.T374S | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV64372195; called by muse, mutect2, varscan2
- MME | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV64707352; called by muse, mutect2, varscan2
- MORC4 | c.674+1G>T p.X225_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99717206; called by muse, mutect2, varscan2
- MOSPD1 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66189316; called by muse, mutect2, varscan2
- MOV10L1 | c.1231del p.T411Pfs*27 | Frame Shift Del (DEL) | VAF 25/188 reads (13%) | catalogued as rs942723014; called by mutect2, pindel, varscan2
- MRGPRE | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV67745708; called by muse, mutect2, varscan2
- MROH7 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs760073833, COSV59871842; called by muse, mutect2, varscan2
- MRPL21 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV62913394; called by muse, mutect2
- MRPS35 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50011426; called by muse, mutect2, varscan2
- MRPS6 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1265818280, COSV62969646; called by muse, mutect2, varscan2
- MTMR4 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV60200588; called by muse, mutect2, varscan2
- MUC16 | c.28138G>T p.G9380C | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1233747761, COSV67465096; called by muse, mutect2, varscan2
- MUC3A | c.8633T>C p.V2878A | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV60215611; called by muse, mutect2, varscan2
- MXD4 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs375438671, COSV61467404; called by muse, mutect2, varscan2
- MYCBP2 | c.11803A>G p.I3935V (on ENST00000357337; = p.I3973V on NM_015057.5) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV62018553; called by muse, mutect2, varscan2
- MYCBPAP | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV60407765; called by muse, mutect2, varscan2
- MYH15 | c.1279C>A p.Q427K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56309742; called by muse, mutect2, varscan2
- MYH6 | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1417882969, COSV62450313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK4 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.4); catalogued as COSV51140990; called by muse, mutect2, varscan2
- MYO10 | c.5175G>A p.V1725= | Splice Region (SNP) | VAF 14/29 reads (48%) | catalogued as COSV57021414; called by muse, mutect2, varscan2
- MYO18B | c.4894C>T p.Q1632* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as rs1280651202, COSV59134067; called by muse, mutect2, varscan2
- MYPOP | c.71A>C p.E24A | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59133625; called by muse, mutect2, varscan2
- MYRF | c.947G>A p.R316H (on ENST00000278836 / NM_001127392.3; = p.R307H on NM_013279.4) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs867720140, COSV53888435; called by muse, mutect2, varscan2
- NAA11 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV54514526, COSV54514831; called by muse, mutect2, varscan2
- NAP1L2 | c.453A>T p.R151S | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1490044093, COSV65172493; called by muse, mutect2, varscan2
- NAV3 | c.4328G>T p.W1443L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57079042; called by muse, mutect2, varscan2
- NAV3 | c.5713G>T p.G1905C (on ENST00000397909 / NM_001024383.2; = p.G1883C on NM_014903.6) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as rs773683739, COSV57079060; called by muse, mutect2, varscan2
- NBAS | c.3924G>A p.M1308I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV55721448; called by muse, mutect2, varscan2
- NCF2 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62315458; called by muse, varscan2
- NCF2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV62315464; called by muse, varscan2
- NCKAP1L | c.2971G>T p.E991* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV53206643; called by muse, mutect2, varscan2
- NCOA2 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs753457737, COSV51219353; called by muse, mutect2, varscan2
- NCOR2 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV62297836; called by muse, mutect2, varscan2
- NDRG2 | c.323G>T p.G108V (on ENST00000298687 / NM_001354570.1; = p.G94V on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100069016; called by muse, mutect2, varscan2
- NDST4 | c.1451T>C p.F484S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV52119430; called by muse, mutect2, varscan2
- NEB | c.15081A>T p.K5027N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51383892; called by muse, mutect2, varscan2
- NEB | c.14380G>T p.D4794Y | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748977335, COSV50806804, COSV51384607; called by muse, mutect2, varscan2
- NEFH | c.1134G>C p.M378I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60217055; called by muse, mutect2, varscan2
- NEK10 | c.2831+1G>T p.X944_splice | Splice Site (SNP) | VAF 21/37 reads (57%) | catalogued as rs752305967, COSV55358520; called by muse, mutect2, varscan2
- NELL1 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.438); catalogued as COSV54263481; called by muse, mutect2
- NELL2 | c.2309C>A p.T770N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.327); catalogued as COSV61574651; called by muse, mutect2, varscan2
- NFRKB | c.1837G>C p.D613H (on ENST00000446488 / NM_001143835.2; = p.D638H on NM_006165.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58757937; called by muse, mutect2, varscan2
- NHLRC2 | c.2075A>T p.D692V | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV65174873; called by muse, mutect2, varscan2
- NIBAN1 | c.2438G>T p.G813V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.025); catalogued as COSV62284647, COSV62287583; called by muse, mutect2, varscan2
- NINL | c.2264G>A p.R755K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54002397; called by muse, mutect2, varscan2
- NKAPL | c.177C>A p.D59E | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV59197880; called by muse, mutect2, varscan2
- NLRC5 | c.4665G>C p.L1555= | Splice Region (SNP) | VAF 29/81 reads (36%) | catalogued as COSV52654859; called by muse, mutect2, varscan2
- NLRP10 | c.1937C>G p.T646R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV60780220; called by muse, mutect2, varscan2
- NMNAT2 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV54268294; called by muse, mutect2, varscan2
- NMT1 | c.807G>T p.R269S | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51959618; called by muse, mutect2, varscan2
- NNT | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52924922; called by muse, mutect2, varscan2
- NOTCH4 | c.4273C>A p.L1425M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV66680619; called by muse, mutect2, varscan2
- NOX1 | c.1553C>G p.A518G | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV54194492; called by muse, mutect2, varscan2
- NOX3 | c.1556A>T p.K519M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV50152100; called by muse, mutect2, varscan2
- NOX3 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50152146; called by muse, mutect2, varscan2
- NPAP1 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV61506881; called by muse, mutect2, varscan2
- NPIPB15 | c.881T>G p.V294G | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.684); catalogued as COSV70437361; called by muse, mutect2, varscan2
- NR4A2 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV59893695; called by muse, mutect2, varscan2
- NR4A3 | c.1007T>G p.V336G | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58244891; called by muse, mutect2, varscan2
- NR5A2 | c.241G>C p.D81H (on ENST00000367362 / NM_205860.3; = p.D35H on NM_003822.5) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV52650047; called by muse, mutect2, varscan2
- NRCAM | c.1459G>C p.E487Q (on ENST00000379028 / NM_001371124.1; = p.E481Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV61036554; called by muse, mutect2, varscan2
- NT5E | c.1680A>C p.L560F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV57628344; called by muse, mutect2, varscan2
- NTNG2 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62366611; called by muse, mutect2, varscan2
- NTRK3 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV58118655, COSV58121837; called by muse, varscan2
- NUDCD2 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV57084652; called by muse, mutect2, varscan2
- NUDT17 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV57907311; called by muse, mutect2, varscan2
- NUP205 | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 127/199 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53658984; called by muse, mutect2, varscan2
- OAS3 | c.2823G>C p.K941N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57445638; called by muse, mutect2, varscan2
- OAT | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 134/201 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV64347677; called by muse, mutect2, varscan2
- OCM | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs757542052, COSV99631407; called by muse, mutect2, varscan2
- OCRL | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV63980894; called by muse, mutect2, varscan2
- OLFML2B | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54196345; called by muse, mutect2, varscan2
- OR10J3 | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV59954294; called by muse, mutect2, varscan2
- OR10K1 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as COSV56871842; called by muse, mutect2, varscan2
- OR10Z1 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV63524815; called by muse, mutect2, varscan2
- OR10Z1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV63524822; called by muse, mutect2, varscan2
- OR11G2 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62132284; called by muse, mutect2, varscan2
- OR13A1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV65572361; called by muse, mutect2, varscan2
- OR13J1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV65069699; called by muse, varscan2
- OR14C36 | c.354T>A p.H118Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58601226; called by muse, varscan2
- OR14C36 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs534027046, COSV58601232; called by muse, varscan2
- OR2G3 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as COSV60681660; called by muse, mutect2, varscan2
- OR2T1 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1318416547, COSV63541870; called by muse, mutect2, varscan2
- OR2T29 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100148278; called by muse, mutect2
- OR2T34 | c.40del p.S14Afs*22 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV100170185; called by mutect2, varscan2
- OR2T4 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV63543987; called by muse, mutect2
- OR2T6 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs867942478, COSV63216234; called by muse, mutect2, varscan2
- OR4A16 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV59043059; called by muse, mutect2, varscan2
- OR4A5 | c.744dup p.V249Cfs*9 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs867369068; called by pindel, varscan2
- OR4C15 | c.732T>A p.D244E (on ENST00000314644; = p.D190E on NM_001001920.2) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV58952789; called by muse, mutect2, varscan2
- OR4C16 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749912465, COSV58941909; called by muse, mutect2, varscan2
- OR4C16 | c.722A>T p.H241L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs146728227, COSV58941916; called by muse, mutect2, varscan2
- OR4C6 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV58603955; called by muse, mutect2, varscan2
- OR4D6 | c.289T>G p.C97G | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55659742, COSV55659933; called by muse, mutect2, varscan2
- OR4K17 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV100210660; called by muse, mutect2, varscan2
- OR4K2 | c.628T>A p.C210S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV53849362; called by muse, mutect2, varscan2
- OR4S2 | c.538C>G p.H180D | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56746848, COSV56748480; called by muse, mutect2, varscan2
- OR51F1 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV58579699; called by muse, mutect2, varscan2
- OR51I1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV66507597, COSV66507877; called by muse, mutect2, varscan2
- OR56B1 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV57722846; called by muse, mutect2, varscan2
- OR5L1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1034103437, COSV61733151, COSV61735372; called by muse, mutect2
- OR5M11 | c.293C>A p.T98K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV73141758; called by muse, mutect2, varscan2
- OR5T3 | c.78G>T p.L26F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as COSV100282920, COSV57380515; called by muse, mutect2, varscan2
- OR8B12 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV60911673; called by muse, mutect2, varscan2
- OR9A4 | c.281T>G p.L94W | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV71885421; called by muse, mutect2, varscan2
- OR9G1 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV56450477; called by muse, mutect2
- OR9Q2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.852); catalogued as rs142991971, COSV61111530; called by muse, mutect2, varscan2
- OR9Q2 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61111915; called by muse, mutect2, varscan2
- OTUD7B | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64916085; called by muse, mutect2, varscan2
- PAK3 | c.1182C>A p.H394Q (on ENST00000262836 / NM_001324328.2; = p.H379Q on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99457432; called by muse, mutect2, varscan2
- PARD6B | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV65404435; called by muse, mutect2, varscan2
- PAX4 | c.911G>C p.W304S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV58388643; called by muse, mutect2, varscan2
- PCDH10 | c.2888G>C p.G963A | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1318202748, COSV52093717; called by muse, mutect2, varscan2
- PCDH11X | c.11T>A p.L4* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV53464540; called by muse, mutect2, varscan2
- PCDH11X | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53439044, COSV53464634; called by muse, mutect2, varscan2
- PCDH15 | c.4280C>A p.P1427Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as COSV57308875; called by muse, mutect2, varscan2
- PCDH15 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.921); catalogued as COSV57308900; called by muse, mutect2, varscan2
- PCDH19 | c.1548C>A p.Y516* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV55262683; called by muse, mutect2, varscan2
- PCDH7 | c.2711G>T p.C904F | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100688361, COSV62338781; called by muse, mutect2
- PCDHA11 | c.2291C>A p.P764H | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV56500300; called by muse, mutect2, varscan2
- PCDHA5 | c.1447G>C p.A483P | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100972516, COSV65352283; called by muse, mutect2, varscan2
- PCDHA5 | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as rs1247134130, COSV65352297; called by muse, mutect2, varscan2
- PCDHB10 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.988); catalogued as COSV53378685; called by muse, mutect2, varscan2
- PCDHB13 | c.1571T>C p.L524P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53396484; called by muse, mutect2, varscan2
- PCDHB3 | c.2320T>G p.F774V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as COSV50569640; called by muse, mutect2, varscan2
- PCDHGA2 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV53945663, COSV53950220; called by muse, mutect2, varscan2
- PCDHGA4 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as rs767396941, COSV53945677; called by muse, mutect2, varscan2
- PCDHGA6 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.045); catalogued as COSV99538579; called by muse, mutect2, varscan2
- PCDHGA6 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99538582; called by muse, mutect2, varscan2
- PCDHGC4 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52751621; called by muse, mutect2, varscan2
- PCNT | c.2581G>T p.A861S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs377283848, COSV64027964; called by muse, mutect2, varscan2
- PDE11A | c.1132G>C p.A378P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.327); catalogued as COSV53694395; called by muse, mutect2, varscan2
- PDE1A | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV59522736; called by muse, mutect2, varscan2
- PDE3A | c.3058G>A p.G1020R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62972673; called by muse, mutect2, varscan2
- PDIA3 | c.791A>T p.Y264F | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV55855908; called by muse, mutect2, varscan2
- PDIA4 | c.1576G>C p.G526R (on ENST00000286091 / NM_001371244.1; = p.G525R on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/126 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV53724734; called by muse, mutect2, varscan2
- PDZRN4 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as COSV68406108; called by muse, mutect2, varscan2
- PGR | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV54801187; called by muse, mutect2, varscan2
- PHEX | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV65075489; called by muse, mutect2, varscan2
- PIK3C2G | c.2903G>T p.R968L (on ENST00000676171; = p.R927L on NM_004570.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56808513, COSV56823107; called by muse, mutect2, varscan2
- PIK3CA | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV55891897; called by muse, mutect2, varscan2
- PIM2 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV55944617; called by muse, mutect2, varscan2
- PKD1L1 | c.7238G>T p.G2413V | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.297); catalogued as COSV51842432; called by muse, mutect2, varscan2
- PKD2 | c.2104G>T p.D702Y | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52938200; called by muse, mutect2, varscan2
- PKHD1 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV61874885; called by muse, mutect2, varscan2
- PKNOX2 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV53545654, COSV53550240; called by muse, mutect2, varscan2
- PKP4 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100733945, COSV61578699; called by muse, mutect2, varscan2
- PLCB1 | c.978C>G p.F326L | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100570047, COSV62049958, COSV62058176; called by muse, mutect2, varscan2
- PLCB4 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV53801391, COSV99596084; called by muse, mutect2, varscan2
- PLCH2 | c.3452C>A p.S1151Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs372578944; called by muse, mutect2, varscan2
- PLCL2 | c.2130G>A p.M710I (on ENST00000615277 / NM_001144382.2; = p.M584I on NM_015184.5) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67622091; called by muse, mutect2, varscan2
- PLEC | c.12867G>A p.M4289I (on ENST00000322810 / NM_201380.4; = p.M4179I on NM_000445.5) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV59634784; called by muse, mutect2, varscan2
- PLEK | c.1030A>C p.M344L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52251788; called by muse, mutect2
- PLEKHG4B | c.1264G>C p.G422R (on ENST00000283426; = p.G778R on NM_052909.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); catalogued as COSV52047304; called by muse, mutect2, varscan2
- PLPP4 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64827886; called by muse, mutect2, varscan2
- PLPPR4 | c.1954C>A p.P652T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs989733017, COSV64565753; called by muse, mutect2, varscan2
- PLXNB3 | c.3370T>G p.F1124V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV62797259; called by muse, mutect2, varscan2
- PNLIP | c.82A>T p.S28C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65040452; called by muse, mutect2, varscan2
- PNLIPRP3 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65047971; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1168G>T p.V390F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65047976; called by muse, mutect2, varscan2
- PNN | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1257755899, COSV53766506; called by muse, mutect2
- POLA1 | c.1769A>G p.K590R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.109); catalogued as COSV66886163; called by muse, mutect2, varscan2
- POLR1B | c.763-1G>C p.X255_splice | Splice Site (SNP) | VAF 27/66 reads (41%) | catalogued as COSV54497921; called by muse, mutect2, varscan2
- POM121C | c.3109G>T p.G1037C (on ENST00000607367; = p.G795C on NM_001099415.3) | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781879973, COSV57545698; called by muse, mutect2, varscan2
- POMP | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV66481460; called by muse, mutect2, varscan2
- POU6F1 | c.1491G>T p.R497= | Splice Region (SNP) | VAF 56/126 reads (44%) | catalogued as COSV61326707; called by muse, mutect2, varscan2
- PPFIBP1 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57291489; called by muse, mutect2, varscan2
- PPP1R10 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 132/208 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV64739194; called by muse, mutect2, varscan2
- PPP1R21 | c.1747A>G p.M583V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV54284547; called by muse, mutect2, varscan2
- PPP2R3C | c.86A>C p.D29A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV54831820, COSV54832724; called by muse, mutect2
- PRAMEF2 | c.1215C>A p.S405R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV53575377; called by muse, mutect2, varscan2
- PRDM5 | c.1586A>G p.N529S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV53360240; called by muse, mutect2, varscan2
- PREPL | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as COSV53216602, COSV53219756; called by muse, mutect2, varscan2
- PRG4 | c.2618C>A p.P873H | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV63355514; called by muse, mutect2, varscan2
- PRICKLE3 | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV66234545; called by muse, mutect2, varscan2
- PRKCH | c.926T>G p.M309R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV60648169; called by muse, mutect2
- PRKD1 | c.1989T>A p.H663Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV59568485; called by muse, mutect2
- PRKDC | c.6143G>A p.G2048E | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58051289, COSV58051677; called by muse, mutect2, varscan2
- PRKN | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58202909, COSV58220892, COSV58225018; called by muse, mutect2, varscan2
- PROX1 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV54778952; called by muse, mutect2, varscan2
- PRR14 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV99788404; called by muse, mutect2, varscan2
- PRR30 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as COSV53206030; called by muse, mutect2
- PRSS22 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50721713; called by muse, mutect2, varscan2
- PSG2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs771999948, COSV68884594; called by muse, mutect2, varscan2
- PSG4 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV54935629; called by muse, mutect2, varscan2
- PSME2 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | catalogued as COSV53756647; called by muse, mutect2, varscan2
- PTGIS | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as rs780217825, COSV54834834; called by muse, mutect2, varscan2
- PTPRD | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs748340591, COSV61945277; called by muse, mutect2, varscan2
- PTPRF | c.3474G>T p.E1158D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63444880; called by muse, mutect2, varscan2
- PTPRK | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100951110; called by muse, mutect2, varscan2
- PTPRT | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778726076, COSV61980595, COSV62037476; called by muse, mutect2, varscan2
- PYGL | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53585845; called by muse, mutect2, varscan2
- QDPR | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV55551865, COSV99845822; called by muse, mutect2, varscan2
- RABGAP1 | c.591-1G>A p.X197_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as COSV58060179; called by muse, mutect2, varscan2
- RABGEF1 | c.1114C>G p.L372V (on ENST00000439720 / NM_001287061.2; = p.L359V on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53162223; called by muse, mutect2, varscan2
- RAD51AP1 | c.589G>C p.E197Q (on ENST00000228843 / NM_001130862.2; = p.E180Q on NM_006479.5) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57409892; called by muse, mutect2, varscan2
- RAI2 | c.1154C>G p.S385C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV58963276, COSV58963360, COSV58964182; called by muse, mutect2, varscan2
- RALGAPA1 | c.2362G>T p.E788* | Nonsense Mutation (SNP) | VAF 189/236 reads (80%) | catalogued as COSV51882558; called by muse, mutect2, varscan2
- RCC1 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65779447; called by muse, mutect2, varscan2
- RDH8 | c.680G>A p.G227D (on ENST00000651512; = p.G207D on NM_015725.4) | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as COSV50674967; called by muse, mutect2, varscan2
- RIMBP2 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV55472114; called by muse, mutect2, varscan2
- RIOX2 | c.271A>T p.S91C | Missense Mutation (SNP) | VAF 122/378 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV57724176, COSV57724591; called by muse, mutect2, varscan2
- RIPOR3 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV50388813; called by muse, mutect2, varscan2
- RLF | c.1801G>T p.V601L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs1420876922, COSV65651786; called by muse, mutect2, varscan2
- RMDN3 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53024023; called by muse, mutect2, varscan2
- RNASE2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as COSV58941189; called by muse, mutect2, varscan2
- RNF130 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV56150339; called by muse, mutect2, varscan2
- RNF150 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV60790586; called by muse, mutect2, varscan2
- RNF2 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV62279316; called by muse, mutect2, varscan2
- RNPEP | c.1139G>C p.R380P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV55240890, COSV55241982; called by mutect2, varscan2
- ROS1 | c.6666C>G p.F2222L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV63853470, COSV63855066; called by muse, mutect2, varscan2
- RP1L1 | c.6817C>A p.P2273T | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV66754851; called by muse, mutect2, varscan2
- RP1L1 | c.2446G>T p.G816W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV66754856; called by muse, mutect2, varscan2
- RP1L1 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV66754863; called by muse, mutect2, varscan2
- RPF2 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV64369463; called by muse, mutect2, varscan2
- RPGR | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140005; called by muse, mutect2, varscan2
- RPS6KC1 | c.2815G>C p.D939H | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.81); catalogued as COSV65299202; called by muse, mutect2, varscan2
- RPTOR | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60808408, COSV60811909; called by muse, mutect2, varscan2
- RRAGC | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65931479; called by muse, mutect2, varscan2
- RSC1A1 | c.1013G>T p.C338F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV100197680, COSV60779696; called by muse, mutect2, varscan2
- RSPH10B2 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99786186; called by muse, mutect2, varscan2
- RTN4 | c.1450G>T p.G484* | Nonsense Mutation (SNP) | VAF 44/135 reads (33%) | catalogued as COSV58267624; called by muse, mutect2, varscan2
- RTP5 | c.1428C>G p.F476L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as rs375279566, COSV58320017; called by muse, mutect2, varscan2
- RYR2 | c.12946G>T p.G4316* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV63684982; called by muse, mutect2, varscan2
- SACS | c.8632G>T p.G2878W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66539747; called by muse, mutect2, varscan2
- SALL4 | c.1947G>T p.M649I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53852121; called by muse, mutect2
- SARAF | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV56357384; called by muse, mutect2, varscan2
- SCN11A | c.4402G>T p.A1468S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV56570182; called by muse, mutect2, varscan2
- SCN8A | c.5887G>A p.E1963K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1057518294, COSV61981391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL2 | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.985); catalogued as COSV62568731; called by muse, mutect2, varscan2
- SDE2 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 34/135 reads (25%) | catalogued as COSV55251262; called by muse, mutect2, varscan2
- SDF2 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55931762; called by muse, mutect2, varscan2
- SEMA3D | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV52389844; called by muse, mutect2, varscan2
- SEMA3D | c.311A>T p.K104M | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52393031; called by muse, mutect2, varscan2
- SEMA5A | c.2688A>C p.P896= | Splice Region (SNP) | VAF 28/70 reads (40%) | catalogued as COSV66792760; called by muse, mutect2, varscan2
- SEMA5A | c.1518G>T p.W506C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66787461; called by muse, mutect2
- SERPINA12 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57943532; called by muse, mutect2, varscan2
- SERPINA4 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as COSV54069868; called by muse, mutect2, varscan2
- SERPINA9 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV54074984; called by muse, mutect2, varscan2
- SETD1A | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV52687604, COSV99353801; called by muse, varscan2
- SETD1A | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52687615; called by muse, varscan2
- SF3A1 | c.680C>G p.S227* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV53168831; called by muse, mutect2, varscan2
- SGIP1 | c.1961C>G p.T654S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV52768498; called by muse, mutect2, varscan2
- SH2B1 | c.1132G>T p.G378* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as COSV59462944; called by muse, varscan2
- SH3D21 | c.1830G>T p.R610S (on ENST00000453908 / NM_001162530.2; = p.R499S on NM_024676.5) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV54634186; called by muse, mutect2, varscan2
- SHOX2 | c.842C>A p.P281H (on ENST00000441443 / NM_006884.3; = p.P305H on NM_003030.4) | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV67463895; called by muse, mutect2, varscan2
- SIGLEC12 | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52461395; called by muse, mutect2
- SIM2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs149282278; called by muse, mutect2, varscan2
- SIPA1L1 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); catalogued as rs1304690354, COSV62170113; called by muse, mutect2
- SKAP2 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV61723506; called by muse, mutect2, varscan2
- SLAMF1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52499136; called by muse, mutect2
- SLC13A3 | c.695A>T p.K232M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51715705; called by muse, mutect2, varscan2
- SLC16A2 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV52084701; called by muse, mutect2, varscan2
- SLC18A1 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV52348042; called by muse, mutect2, varscan2
- SLC22A7 | c.1492T>C p.Y498H (on ENST00000372585 / NM_153320.2; = p.Y496H on NM_006672.3) | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51483894; called by muse, mutect2
- SLC24A2 | c.988C>G p.R330G | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV53864672; called by muse, mutect2, varscan2
- SLC24A5 | c.1425_1426insA p.L476Ifs*11 | Frame Shift Ins (INS) | VAF 32/61 reads (52%) | catalogued as COSV99981669; called by mutect2, pindel, varscan2
- SLC25A14 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54418096; called by muse, mutect2, varscan2
- SLC25A48 | c.610G>C p.E204Q (on ENST00000650267; = p.E150Q on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV50848960; called by muse, mutect2, varscan2
- SLC25A53 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1166172920, COSV100655997; called by muse, mutect2, varscan2
- SLC26A7 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52593053; called by muse, mutect2, varscan2
- SLC35D3 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV59377762; called by muse, mutect2, varscan2
- SLC38A8 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765635340, COSV55306451, COSV55307764; called by muse, mutect2, varscan2
- SLC44A5 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63764646; called by muse, mutect2, varscan2
- SLC45A1 | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1209448627, COSV57095320; called by muse, mutect2, varscan2
- SLC49A3 | c.1639G>T p.A547S (on ENST00000404286 / NM_001294341.2; = p.A546S on NM_032219.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs143423821, COSV59140270; called by muse, mutect2, varscan2
- SLC4A2 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV59657034; called by muse, mutect2, varscan2
- SLC5A2 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); catalogued as COSV57891487; called by muse, mutect2, varscan2
- SLC5A7 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV50891506; called by muse, mutect2, varscan2
- SLC6A15 | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57023490; called by muse, mutect2, varscan2
- SLC6A15 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57023504; called by muse, mutect2, varscan2
- SLC6A5 | c.2284T>G p.L762V | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs1232412390, COSV54226426; called by muse, mutect2
- SLC7A3 | c.1364A>C p.K455T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV53227412; called by muse, mutect2, varscan2
- SLC8A1 | c.1093C>G p.R365G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60480168, COSV60495926; called by muse, mutect2, varscan2
- SLC8A3 | c.2190C>A p.Y730* (on ENST00000381269 / NM_183002.3; = p.Y728* on NM_033262.4) | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53687621; called by muse, mutect2, varscan2
- SLC9A9 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 58/101 reads (57%) | catalogued as COSV57226811, COSV57246826; called by muse, mutect2, varscan2
- SLC9C1 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.773); catalogued as COSV59888117; called by muse, mutect2, varscan2
- SLFN11 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as COSV57698787; called by muse, mutect2, varscan2
- SLITRK1 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV65675537, COSV65676796; called by muse, mutect2, varscan2
- SMARCA1 | c.1233G>C p.K411N | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64411944; called by muse, mutect2, varscan2
- SNTG1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 43/237 reads (18%) | catalogued as COSV52442654; called by muse, mutect2, varscan2
- SNX19 | c.1455G>T p.K485N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV56285625; called by muse, mutect2, varscan2
- SNX29 | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60052255, COSV60059036; called by muse, mutect2, varscan2
- SOHLH2 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65901970; called by muse, mutect2, varscan2
- SORCS1 | c.3272T>C p.L1091P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53865606; called by muse, mutect2
- SORCS1 | c.2226C>A p.C742* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53862462; called by muse, mutect2, varscan2
- SORCS1 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53857469; called by mutect2, varscan2
- SORCS3 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.308); catalogued as COSV63794518, COSV63795008; called by muse, mutect2, varscan2
- SOX14 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV60162813; called by muse, mutect2, varscan2
- SP100 | c.2408G>A p.R803K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs545978500, COSV60844624; called by muse, mutect2, varscan2
- SPACA1 | c.711G>T p.L237F | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52759818; called by muse, mutect2, varscan2
- SPAM1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs755668572, COSV56143582; called by muse, mutect2, varscan2
- SPEM2 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV61603872; called by muse, mutect2, varscan2
- SPOCK3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.091); catalogued as rs1422436706, COSV62718113; called by muse, mutect2, varscan2
- SPTA1 | c.1804A>G p.K602E | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); catalogued as COSV63752886; called by muse, mutect2, varscan2
- SRCAP | c.4715T>C p.L1572P | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV52672458; called by muse, mutect2, varscan2
- SRP54 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs764460322, COSV53739768; called by muse, mutect2, varscan2
- SRSF4 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65694609, COSV65695757; called by muse, mutect2, varscan2
- ST8SIA3 | c.831G>T p.W277C | Missense Mutation (SNP) | VAF 35/121 reads (29%) | PolyPhen probably damaging (0.971); catalogued as COSV100129622, COSV60654146; called by muse, mutect2, varscan2
- STAB2 | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778645418, COSV66338774; called by muse, mutect2, varscan2
- STAG2 | c.1393G>T p.V465F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54356033; called by muse, mutect2, varscan2
- STAG2 | c.2347G>T p.V783F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV54358156; called by muse, mutect2, varscan2
- STARD3 | c.1233+1G>T p.X411_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | catalogued as COSV59223615; called by muse, mutect2, varscan2
- STARD8 | c.1876T>A p.S626T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV52926144; called by muse, mutect2, varscan2
- STAT2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV100028909; called by muse, mutect2, varscan2
- STIM2 | c.1491G>T p.G497= | Splice Region (SNP) | VAF 29/120 reads (24%) | catalogued as rs140282649; called by muse, mutect2, varscan2
- STK33 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV59400799; called by muse, mutect2, varscan2
- STK36 | c.1098G>T p.W366C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55326505; called by muse, mutect2, varscan2
- STRA8 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs1312203249, COSV51961429; called by muse, mutect2, varscan2
- STYXL2 | c.3136C>A p.P1046T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV54805001; called by muse, mutect2, varscan2
- SUCO | c.982A>T p.S328C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55265178; called by muse, mutect2, varscan2
- SUCO | c.3717G>T p.E1239D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1469556194, COSV55265203, COSV55271080; called by muse, mutect2, varscan2
- SVEP1 | c.4726C>T p.Q1576* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV65683266; called by muse, mutect2, varscan2
- SVOPL | c.1021C>A p.P341T (on ENST00000419765; = p.P189T on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as COSV55990837; called by muse, mutect2, varscan2
- SWSAP1 | c.598C>T p.R200* (on ENST00000312423; = p.R221* on NM_175871.4) | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs748176447, COSV55800253; called by mutect2, varscan2
- TAB3 | c.2008A>T p.T670S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV55836870; called by muse, mutect2, varscan2
- TAFA2 | c.70T>A p.W24R | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV69178200; called by muse, mutect2, varscan2
- TAOK2 | c.1509G>T p.Q503H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54235623; called by muse, mutect2, varscan2
- TAOK3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1048516245, COSV66825797; called by muse, mutect2, varscan2
- TARS1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV54309152; called by muse, mutect2, varscan2
- TAS1R3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs745746390, COSV59563358; called by muse, mutect2, varscan2
- TBC1D17 | c.1413G>T p.R471S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55578525; called by muse, mutect2, varscan2
- TCF25 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs201329641, COSV54527524; called by muse, mutect2, varscan2
- TCF4 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61896455; called by muse, mutect2, varscan2
- TCL1B | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61551988; called by muse, mutect2, varscan2
- TECRL | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV67085425; called by muse, mutect2, varscan2
- TEKT3 | c.1231T>G p.L411V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58627555; called by muse, mutect2, varscan2
- TEX11 | c.1590T>A p.D530E (on ENST00000344304; = p.D515E on NM_031276.3) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV60230661; called by muse, mutect2, varscan2
- TFF2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.422); catalogued as rs1446935170, COSV52296214; called by muse, mutect2, varscan2
- TG | c.3421A>T p.S1141C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV55075799; called by muse, mutect2, varscan2
- TGM6 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV52479951; called by muse, mutect2, varscan2
- TGM6 | c.260C>G p.A87G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52479959; called by muse, mutect2, varscan2
428 further variants in this file (162 protein-altering or splice-affecting, 238 silent, 28 other) are not listed here.
